Somatic mutation profile of tumor specimen TCGA-HT-7469-01A (aliquot TCGA-HT-7469-01A-11D-2253-08) from TCGA case TCGA-HT-7469, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 30.4 years (11,097 days).
Specimen TCGA-HT-7469-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fc52f145-725a-413d-90e9-556d29911044.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7469-10B (Blood Derived Normal), aliquot TCGA-HT-7469-10B-01D-2253-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9ab30dd5-ac93-4672-bade-994eccc1df74

The open-access MAF lists 40 somatic variants for this specimen: 28 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 18, Silent 12, Frame Shift Del 5, Nonsense Mutation 2, Splice Site 1, Splice Region 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADARB1 | c.1808G>A p.R603Q (on ENST00000360697 / NM_001346687.2; = p.R563Q on NM_001112.4) | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1364071684, COSV62346726; ClinVar: pathogenic; called by muse, mutect2, varscan2
- H3-3A | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 19/47 reads (40%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.773); catalogued as rs1553260624, COSV64731793, COSV64731830, COSV64732212; ClinVar: other; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 37/105 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.373A>C p.T125P | Missense Mutation (SNP) | VAF 49/101 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057520003, CM156966, COSV52780750, COSV52951418, COSV53606217; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- CCDC30 | c.916C>T p.R306* (on ENST00000340612; = p.R263* on NM_001080850.3) | Nonsense Mutation (SNP) | VAF 39/107 reads (36%) | catalogued as rs780702656, COSV59604704; called by muse, mutect2, varscan2
- DMC1 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780204406, COSV53260243; called by muse, mutect2, varscan2
- EZHIP | c.1043G>A p.R348H | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs1557318879, COSV100539415; called by muse, mutect2, varscan2
- FRA10AC1 | c.51_52del p.C17Wfs*12 | Frame Shift Del (DEL) | VAF 4/37 reads (11%) | catalogued as rs764976937; called by pindel, varscan2
- FRMD4A | c.300G>A p.R100= | Splice Region (SNP) | VAF 40/99 reads (40%) | catalogued as rs559657039, COSV52731946; called by muse, mutect2, varscan2
- FSTL5 | c.487C>T p.Q163* | Nonsense Mutation (SNP) | VAF 12/32 reads (38%) | catalogued as COSV60216751; called by muse, mutect2, varscan2
- IL1RL2 | c.596T>G p.L199R | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV51817524; called by muse, mutect2, varscan2
- KMT2A | c.7724C>T p.P2575L | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as COSV63290316; called by muse, mutect2, varscan2
- MGAT2 | c.1234_1237del p.T412Sfs*8 | Frame Shift Del (DEL) | VAF 27/68 reads (40%) | catalogued as rs776720499; called by mutect2, pindel, varscan2
- MYF5 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 39/102 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.966); catalogued as COSV57355989; called by muse, mutect2, varscan2
- MYH6 | c.3029A>G p.D1010G | Missense Mutation (SNP) | VAF 58/114 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV62453127; called by muse, mutect2, varscan2
- OR8B4 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV62070271; called by muse, mutect2, varscan2
- PDGFRA | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57271640, COSV57272265; called by muse, mutect2, varscan2
- SEC14L4 | c.1096G>A p.D366N | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs564814217, COSV55398756; called by muse, mutect2, varscan2
- SPATA31A1 | c.3991T>A p.S1331T | Missense Mutation (SNP) | VAF 121/297 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0.444); catalogued as rs1401992812; called by muse, mutect2, varscan2
- TBXT | c.563C>T p.P188L | Missense Mutation (SNP) | VAF 76/429 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV51619396; called by muse, mutect2, varscan2
- TMEFF2 | c.476C>A p.T159K | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.632); catalogued as COSV55837298; called by muse, mutect2, varscan2
- TXNDC11 | c.1331C>T p.T444M (on ENST00000356957 / NM_001303447.2; = p.T417M on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as rs781579524, COSV51601697; called by muse, mutect2, varscan2
- ZFP64 | c.1322G>A p.R441H | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs764218342, COSV53804352; called by muse, mutect2, varscan2
- ZNF217 | c.450C>G p.H150Q | Missense Mutation (SNP) | VAF 10/195 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56600580; called by muse, mutect2
- ATRX | c.1237_1238del p.L413Kfs*20 | Frame Shift Del (DEL) | VAF 154/210 reads (73%) | called by mutect2, pindel, varscan2
- PDGFRA | c.932-1_934del p.X311_splice | Splice Site (DEL) | VAF 21/103 reads (20%) | called by mutect2, pindel, varscan2
- SLC12A9 | c.1013_1021delinsG p.A338Gfs*36 | Frame Shift Del (DEL) | VAF 38/175 reads (22%) | called by pindel, varscan2*
- SLC26A4 | c.411_414del p.V138Dfs*6 | Frame Shift Del (DEL) | VAF 12/62 reads (19%) | called by mutect2, pindel, varscan2
- AL592490.1 | c.1299C>T p.N433= | Silent (SNP) | VAF 23/125 reads (18%) | catalogued as rs1266806470, COSV69427268; called by muse, mutect2, varscan2
- CHGB | c.2033G>A p.*678= | Silent (SNP) | VAF 28/60 reads (47%) | catalogued as COSV66761406; called by muse, mutect2, varscan2
- EDAR | c.24G>A p.T8= | Silent (SNP) | VAF 36/136 reads (26%) | catalogued as rs771046519, COSV51500015, COSV51500127, COSV99304016; called by muse, mutect2, varscan2
- HR | c.1689G>A p.G563= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs1448988973, COSV57193888; called by muse, mutect2, varscan2
- MCTP1 | c.1492C>A p.R498= | Silent (SNP) | VAF 26/111 reads (23%) | catalogued as COSV56527586; called by muse, mutect2, varscan2
- MX2 | c.1560C>T p.L520= | Silent (SNP) | VAF 25/109 reads (23%) | catalogued as COSV58098403; called by muse, mutect2, varscan2
- NSFL1C | c.132C>T p.D44= | Silent (SNP) | VAF 16/220 reads (7%) | catalogued as rs191322139, COSV53792185; called by muse, mutect2
- POR | c.225G>A p.K75= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as COSV67517870; called by muse, mutect2, varscan2
- RYR1 | c.12237C>T p.Y4079= | Silent (SNP) | VAF 39/112 reads (35%) | catalogued as rs767437406, COSV62087406; ClinVar: likely benign; called by muse, mutect2, varscan2
- SYCP1 | c.354A>G p.K118= | Silent (SNP) | VAF 16/85 reads (19%) | catalogued as COSV65696526, COSV65699991; called by muse, mutect2, varscan2
- TLR1 | c.714G>A p.A238= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs146940675; called by muse, mutect2, varscan2
- UCN | c.309G>A p.A103= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV51989715; called by muse, mutect2, varscan2
